Somatic mutation profile of tumor specimen C3L-06311-05 (aliquot CPT0363210009) from CPTAC case C3L-06311, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 67.0 years (24,484 days).
Specimen C3L-06311-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33c82a0f-bf2c-41a4-a5de-5be6215581ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06311-31 (Blood Derived Normal), aliquot CPT0363270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22164517-0004-452c-acb9-b7b8422c6a90

The open-access MAF lists 300 somatic variants for this specimen: 182 protein-altering or splice-affecting, 101 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 101, Nonsense Mutation 11, Intron 9, 5'Flank 4, Splice Region 4, Splice Site 4, 3'UTR 2, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS16 | c.2801G>A p.G934E | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV99943602; called by muse, mutect2, varscan2
- AIF1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 208/599 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV61962630; called by muse, mutect2, varscan2
- ARHGAP23 | c.2246G>A p.G749D | Missense Mutation (SNP) | VAF 92/266 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.89); catalogued as rs1374452795; called by muse, mutect2, varscan2
- BHMG1 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV71837036; called by muse, mutect2, varscan2
- BLM | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1173491187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLM | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs371100621, COSV61925427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C19orf54 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 132/537 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99648525; called by muse, mutect2, varscan2
- CDH5 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV58519714; called by muse, mutect2, varscan2
- CHRNA9 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs759080788; called by muse, mutect2, varscan2
- CLEC18B | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 93/502 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs764888803; called by muse, varscan2
- CLVS2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51569741, COSV99253768; called by muse, mutect2, varscan2
- CNGA4 | c.1268-1G>A p.X423_splice | Splice Site (SNP) | VAF 72/237 reads (30%) | catalogued as COSV101171767; called by muse, mutect2, varscan2
- COL9A1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated (0.72); PolyPhen probably damaging (1); catalogued as COSV61833974; called by muse, mutect2, varscan2
- CORIN | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56698652; called by muse, mutect2, varscan2
- CPEB4 | c.601A>T p.N201Y | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV99437072; called by muse, mutect2, varscan2
- CPXCR1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 109/201 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as rs532425618, COSV52162454; called by muse, mutect2, varscan2
- CRLF1 | c.397C>T p.L133= | Splice Region (SNP) | VAF 79/269 reads (29%) | catalogued as rs747750093; called by muse, mutect2, varscan2
- CT47B1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 223/361 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV64890889; called by muse, mutect2, varscan2
- CYP2D7 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs541031533, COSV100809660; called by muse, mutect2, varscan2
- CYP4A11 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 160/321 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV60223674; called by muse, mutect2, varscan2
- DCC | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs370927048; called by muse, mutect2, varscan2
- DENND2C | c.1474G>A p.E492K (on ENST00000393274 / NM_001256404.2; = p.E435K on NM_198459.4) | Missense Mutation (SNP) | VAF 125/296 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV67920452; called by muse, mutect2, varscan2
- DNAH7 | c.3922G>A p.D1308N | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773295727; called by muse, mutect2, varscan2
- DNMBP | c.3992A>G p.N1331S | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs757689446; called by muse, mutect2
- DRAM1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.305); catalogued as rs1049137596; called by muse, mutect2, varscan2
- FAM170B | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 117/296 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as rs868477134, COSV61253906; called by muse, mutect2, varscan2
- FAM47A | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV60495360; called by muse, mutect2, varscan2
- FFAR3 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 81/530 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs551288253; called by muse, mutect2, varscan2
- GOSR1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771601377, COSV56718768; called by muse, mutect2, varscan2
- GUCY1A2 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56488417; called by muse, mutect2, varscan2
- H2AC1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 136/406 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV51237144; called by muse, mutect2, varscan2
- HDAC4 | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 79/323 reads (24%) | catalogued as rs1553611431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPH | c.3034C>T p.R1012W (on ENST00000343002; = p.R745W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1205946514, COSV57965458; called by muse, mutect2, varscan2
- IL21R | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1567374370, COSV100560522; called by muse, mutect2, varscan2
- ITLN1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV100406312, COSV100406369; called by muse, mutect2, varscan2
- JAKMIP3 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs768911626, COSV53820916; called by muse, mutect2, varscan2
- KCNK10 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768896504; called by muse, mutect2, varscan2
- KCNT2 | c.3374C>T p.T1125I | Missense Mutation (SNP) | VAF 86/366 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1372535491; called by muse, mutect2, varscan2
- KIAA1217 | c.4609G>A p.E1537K | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56821442; called by muse, mutect2, varscan2
- KRT6B | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 143/1029 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as rs1470125049; called by muse, mutect2, varscan2
- KRT6C | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1365310478; called by mutect2, varscan2
- KRTAP13-4 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 105/384 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs147969446, COSV61878992; called by muse, mutect2, varscan2
- LGSN | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV65726718; called by muse, mutect2, varscan2
- LRRC63 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs1300658469; called by muse, mutect2, varscan2
- MALRD1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs894393101; called by muse, mutect2, varscan2
- MC2R | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 121/468 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs139860273; called by muse, mutect2, varscan2
- MORC2 | c.1955A>G p.K652R (on ENST00000397641 / NM_001303256.3; = p.K590R on NM_014941.3) | Missense Mutation (SNP) | VAF 116/509 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs774005231; called by muse, mutect2, varscan2
- MRPL42 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs763030799, COSV62356912; called by muse, mutect2, varscan2
- MYO16 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.441); catalogued as rs1341921077; called by muse, mutect2, varscan2
- NAT2 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 97/383 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1490596479, COSV54063161; called by muse, mutect2, varscan2
- NLRP9 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 113/413 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300516946; called by muse, mutect2, varscan2
- OR2T27 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 54/465 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs752438465, COSV61282401; called by muse, mutect2, varscan2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR5C1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 281/466 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs147276457; called by muse, mutect2, varscan2
- PPP4R3C | c.2485C>T p.H829Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs1476689335; called by muse, mutect2, varscan2
- PRDM10 | c.1984C>T p.H662Y | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV58805233; called by muse, varscan2
- PROSER1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61487269; called by muse, mutect2, varscan2
- PTCHD4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as rs534112009, COSV59785677, COSV59787501; called by muse, mutect2, varscan2
- PTPRN | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 184/579 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs724159912, COSV55346541; called by muse, mutect2, varscan2
- PTPRT | c.3859T>C p.Y1287H | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV61992191; called by muse, mutect2, varscan2
- PXDNL | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1390297647, COSV62487318; called by muse, mutect2, varscan2
- RAB31 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV71261982; called by muse, mutect2, varscan2
- RHOT1 | c.867C>T p.P289= | Splice Region (SNP) | VAF 58/229 reads (25%) | catalogued as rs774116598, COSV61714553; called by muse, varscan2
- RIPOR3 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50404497; called by muse, mutect2, varscan2
- SERPINA12 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV57945134; called by muse, mutect2, varscan2
- SLC17A6 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV54137115; called by muse, mutect2, varscan2
- SPIC | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54691251; called by muse, mutect2, varscan2
- STAC2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 133/366 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs140937359; called by muse, mutect2, varscan2
- SYT9 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV59615603; called by muse, mutect2, varscan2
- TBC1D21 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100311299; called by muse, mutect2, varscan2
- TBRG4 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 276/575 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51834391; called by muse, mutect2, varscan2
- TC2N | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 76/250 reads (30%) | catalogued as rs537836079, COSV61746369; called by muse, mutect2, varscan2
- TENM3 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 84/325 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756344945; called by muse, mutect2, varscan2
- TENT5D | c.770A>C p.N257T | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1177074819; called by muse, mutect2
- TLL1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.538); catalogued as COSV50322218; called by muse, mutect2, varscan2
- TLR9 | c.2833G>A p.G945S | Missense Mutation (SNP) | VAF 100/445 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62347105; called by muse, mutect2, varscan2
- TMEM119 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 119/429 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1389003638, COSV67188976; called by muse, mutect2, varscan2
- TMOD2 | c.858A>C p.E286D | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs1273588529; called by muse, mutect2, varscan2
- TRANK1 | c.7867G>A p.E2623K | Missense Mutation (SNP) | VAF 122/370 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1197024240, COSV57154401; called by muse, mutect2, varscan2
- TRIM31 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 168/595 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs201488158; called by muse, mutect2, varscan2
- UGT1A7 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs765046704, COSV100693164; called by muse, mutect2, varscan2
- USP43 | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 140/477 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV53303964; called by muse, mutect2
- VWA7 | c.723G>A p.G241= | Splice Region (SNP) | VAF 121/455 reads (27%) | catalogued as COSV65155375; called by muse, mutect2, varscan2
- WNK2 | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 295/519 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52942453; called by muse, mutect2, varscan2
- ZAN | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 214/455 reads (47%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.943); catalogued as rs772729013; called by muse, mutect2, varscan2
- ZC3H11B | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 96/409 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1161877769, COSV65844808; called by muse, mutect2, varscan2
- ZFYVE26 | c.5398C>T p.P1800S | Missense Mutation (SNP) | VAF 108/439 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61328515; called by muse, mutect2, varscan2
- ZNF676 | c.1418G>A p.R473K (on ENST00000650058; = p.R441K on NM_001001411.3) | Missense Mutation (SNP) | VAF 117/438 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.047); catalogued as COSV101236165, COSV68092102, COSV68092115; called by muse, mutect2, varscan2
- ZNF676 | c.1163A>C p.K388T (on ENST00000650058; = p.K356T on NM_001001411.3) | Missense Mutation (SNP) | VAF 114/484 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68092723; called by muse, mutect2, varscan2
- ABCC8 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 111/388 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- AC004922.1 | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 131/457 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ADAMTS7 | c.4902C>T p.P1634= | Splice Region (SNP) | VAF 76/278 reads (27%) | called by muse, varscan2
- ADARB2 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AK7 | c.780_781del p.X260_splice | Splice Site (DEL) | VAF 96/312 reads (31%) | called by pindel, varscan2
- ARHGAP23 | c.2336C>G p.T779S | Missense Mutation (SNP) | VAF 130/424 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- ARHGAP45 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 148/558 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- ATP2B1 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHMT2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf210 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 142/268 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, varscan2
- CCDC14 | c.2621C>A p.S874Y (on ENST00000488653; = p.S826Y on NM_022757.5) | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD8B | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 109/417 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFHR4 | c.1208C>T p.S403F (on ENST00000367416 / NM_001201551.2; = p.S157F on NM_006684.5) | Missense Mutation (SNP) | VAF 64/326 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CNGA4 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNN3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CPXM1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- DCAF8L1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 135/241 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DRG1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EFNB2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELMOD3 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 81/299 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- EPPK1 | c.1897G>A p.G633R | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ERBB4 | c.3644C>T p.T1215I | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EXD1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 93/326 reads (29%) | called by muse, mutect2, varscan2
- FAM227B | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 65/283 reads (23%) | called by muse, varscan2
- FAM78A | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 164/286 reads (57%) | called by muse, mutect2, varscan2
- FBXO28 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 142/523 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FILIP1 | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- FSIP2 | c.16936G>A p.E5646K | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD10 | c.283T>C p.C95R | Missense Mutation (SNP) | VAF 129/468 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GP2 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 122/380 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- HAUS6 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- HDAC4 | c.2285G>A p.W762* | Nonsense Mutation (SNP) | VAF 81/324 reads (25%) | called by muse, mutect2, varscan2
- ITIH4 | c.2771C>T p.S924F | Missense Mutation (SNP) | VAF 85/325 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KBTBD11 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 148/481 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KCNT1 | c.2907G>A p.M969I (on ENST00000488444; = p.M988I on NM_020822.3) | Missense Mutation (SNP) | VAF 121/216 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KIF26B | c.4804C>T p.R1602* | Nonsense Mutation (SNP) | VAF 177/630 reads (28%) | called by muse, varscan2
- KMT2B | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 112/422 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- KRTAP4-8 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 191/709 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2
- LRP2 | c.3028C>T p.H1010Y | Missense Mutation (SNP) | VAF 100/413 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LUC7L | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 117/433 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARK1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- MEI1 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTMR7 | c.1230G>A p.M410I | Missense Mutation (SNP) | VAF 107/392 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MUC16 | c.10058G>A p.G3353E | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- MUC17 | c.3884C>T p.A1295V | Missense Mutation (SNP) | VAF 106/864 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NWD2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR2B6 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 68/271 reads (25%) | called by muse, mutect2, varscan2
- OR4E1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- P2RY2 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 115/528 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PERM1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 475/675 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0.316); called by mutect2, varscan2
- PIGG | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 123/419 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLD1 | c.2041C>T p.L681F | Missense Mutation (SNP) | VAF 158/520 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKDC | c.9834_9841delinsA p.S3279Afs*3 | Frame Shift Del (DEL) | VAF 106/460 reads (23%) | called by pindel, varscan2*
- PRTG | c.2623+1G>A p.X875_splice | Splice Site (SNP) | VAF 74/215 reads (34%) | called by muse, mutect2, varscan2
- RBL2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- RGPD2 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 81/293 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGSL1 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 114/426 reads (27%) | called by muse, mutect2, varscan2
- RHOT1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RP1L1 | c.5510C>G p.A1837G | Missense Mutation (SNP) | VAF 154/494 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SAGE1 | c.1960C>T p.H654Y | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- SDK1 | c.5896G>A p.D1966N | Missense Mutation (SNP) | VAF 98/603 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SEPTIN11 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 42/245 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 123/406 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC12A9 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 106/651 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SLC16A6 | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SLC27A2 | c.638A>C p.E213A | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC9B2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRK | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 142/464 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SPAG17 | c.5608G>A p.E1870K | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SPIC | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- STAC | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF6 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 347/659 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TCF21 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- TDRD12 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TEX15 | c.622C>T p.P208S (on ENST00000638951; = p.P204S on NM_001350162.2) | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- TGS1 | c.2558C>T p.T853I | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLR4 | c.1672A>C p.T558P (on ENST00000355622 / NM_138554.5; = p.T518P on NM_003266.4) | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.485); called by muse, mutect2
- TMEM156 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TNRC6B | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 139/452 reads (31%) | called by muse, mutect2, varscan2
- TRIM61 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 74/584 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TTN | c.13793G>A p.R4598K (on ENST00000591111; = p.R3671K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/371 reads (25%) | PolyPhen benign (0.018); called by muse, mutect2, varscan2
- UMODL1 | c.2960G>A p.G987E (on ENST00000408910 / NM_001004416.2; = p.G1115E on NM_173568.3) | Missense Mutation (SNP) | VAF 197/538 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13A | c.5637G>A p.M1879I | Missense Mutation (SNP) | VAF 196/342 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 188/369 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDR35 | c.1291C>T p.P431S (on ENST00000345530 / NM_001006657.2; = p.P420S on NM_020779.4) | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR61 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZFPM2 | c.41-1G>A p.X14_splice | Splice Site (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF423 | c.343C>T p.P115S (on ENST00000563137 / NM_001379286.1; = p.P107S on NM_015069.4) | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF469 | c.9200C>T p.A3067V (on ENST00000437464; = p.A3095V on NM_001367624.2) | Missense Mutation (SNP) | VAF 121/485 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.121); called by muse, varscan2
- ZNF676 | c.1759C>T p.H587Y (on ENST00000650058; = p.H555Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF683 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 191/528 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC10 | c.3678C>T p.P1226= (on ENST00000372530 / NM_001198934.2; = p.P1198= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/350 reads (25%) | catalogued as rs1355699855; called by muse, mutect2, varscan2
- AC139530.2 | c.186C>T p.P62= | Silent (SNP) | VAF 138/445 reads (31%) | catalogued as COSV100230614, COSV61268313; called by muse, mutect2, varscan2
- ACVR1 | c.1206C>T p.V402= | Silent (SNP) | VAF 86/339 reads (25%) | catalogued as rs769927793; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3648G>A p.R1216= | Silent (SNP) | VAF 154/266 reads (58%) | called by muse, mutect2, varscan2
- ALLC | c.201G>A p.G67= | Silent (SNP) | VAF 77/312 reads (25%) | catalogued as rs769807402, COSV99378048; called by muse, mutect2, varscan2
- ALPI | c.654C>T p.I218= | Silent (SNP) | VAF 65/235 reads (28%) | catalogued as COSV55016319; called by muse, mutect2, varscan2
- ALPK2 | c.1131C>T p.F377= | Silent (SNP) | VAF 88/408 reads (22%) | called by muse, mutect2, varscan2
- APOBR | c.231G>A p.G77= | Silent (SNP) | VAF 124/442 reads (28%) | catalogued as rs751405824; called by muse, mutect2, varscan2
- APOL4 | c.846C>T p.T282= (on ENST00000352371 / NM_145660.2; = p.T279= on NM_030643.4) | Silent (SNP) | VAF 138/447 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.4050C>T p.P1350= (on ENST00000398564; = p.P1325= on NM_014629.4) | Silent (SNP) | VAF 159/572 reads (28%) | called by muse, mutect2, varscan2
- ASF1B | c.66C>T p.F22= | Silent (SNP) | VAF 82/348 reads (24%) | catalogued as rs1331154035; called by muse, mutect2, varscan2
- C1S | c.450C>T p.F150= | Silent (SNP) | VAF 96/330 reads (29%) | catalogued as rs1555161754; called by muse, mutect2, varscan2
- CA10 | c.838C>T p.L280= | Silent (SNP) | VAF 111/363 reads (31%) | catalogued as COSV53346354, COSV53347800; called by muse, mutect2, varscan2
- CAB39L | c.747C>T p.I249= | Silent (SNP) | VAF 101/366 reads (28%) | called by muse, mutect2, varscan2
- CABP5 | c.9C>T p.F3= | Silent (SNP) | VAF 100/406 reads (25%) | catalogued as COSV53154014; called by muse, mutect2, varscan2
- CCBE1 | c.328C>T p.L110= | Silent (SNP) | VAF 123/407 reads (30%) | catalogued as rs909030394, COSV101232898, COSV67949808; called by muse, mutect2, varscan2
- CCDC88C | c.4437G>A p.G1479= | Silent (SNP) | VAF 89/360 reads (25%) | called by muse, mutect2, varscan2
- CD33 | c.25C>T p.L9= | Silent (SNP) | VAF 134/515 reads (26%) | called by muse, mutect2, varscan2
- CEACAM20 | c.459C>T p.F153= | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- CFAP43 | c.3297C>T p.I1099= | Silent (SNP) | VAF 103/294 reads (35%) | catalogued as rs756475731, COSV63854927; called by muse, mutect2, varscan2
- CLCN1 | c.1359G>A p.R453= | Silent (SNP) | VAF 276/554 reads (50%) | catalogued as COSV58372466; called by muse, mutect2, varscan2
- CSMD3 | c.1854C>T p.L618= (on ENST00000297405 / NM_001363185.1; = p.L514= on NM_052900.3) | Silent (SNP) | VAF 64/255 reads (25%) | catalogued as COSV52348562, COSV99844285; called by muse, mutect2, varscan2
- DCC | c.1314C>T p.V438= | Silent (SNP) | VAF 87/360 reads (24%) | catalogued as COSV59105681; called by muse, mutect2, varscan2
- DMXL2 | c.4567C>T p.L1523= | Silent (SNP) | VAF 105/377 reads (28%) | catalogued as COSV51846715; called by muse, mutect2, varscan2
- DNAH7 | c.3921G>A p.T1307= | Silent (SNP) | VAF 48/216 reads (22%) | catalogued as rs760787754, COSV100416756; called by muse, mutect2, varscan2
- DOCK10 | c.5904C>T p.F1968= | Silent (SNP) | VAF 146/471 reads (31%) | catalogued as rs768117264, COSV51379969; called by muse, mutect2, varscan2
- EMILIN3 | c.636G>A p.R212= | Silent (SNP) | VAF 141/594 reads (24%) | catalogued as rs762667471, COSV100182734; called by muse, mutect2, varscan2
- EPS8L2 | c.2013C>T p.G671= | Silent (SNP) | VAF 125/424 reads (29%) | called by muse, mutect2, varscan2
- FAM20C | c.642C>T p.S214= | Silent (SNP) | VAF 332/712 reads (47%) | catalogued as rs1323749053, COSV58237385; called by mutect2, varscan2
- FAM78A | c.348C>T p.L116= | Silent (SNP) | VAF 162/285 reads (57%) | called by muse, mutect2, varscan2
- FDPS | c.15C>G p.R5= | Silent (SNP) | VAF 93/373 reads (25%) | called by muse, mutect2, varscan2
- GALNT16 | c.1248G>A p.L416= | Silent (SNP) | VAF 82/349 reads (23%) | called by muse, mutect2, varscan2
- GPHN | c.1911C>T p.L637= (on ENST00000315266 / NM_001377519.1; = p.L670= on NM_020806.5) | Silent (SNP) | VAF 141/440 reads (32%) | catalogued as COSV100017329; called by muse, mutect2, varscan2
- HSD3B7 | c.826C>T p.L276= | Silent (SNP) | VAF 118/467 reads (25%) | called by muse, mutect2, varscan2
- IFT140 | c.1698C>T p.V566= | Silent (SNP) | VAF 142/491 reads (29%) | catalogued as rs966210084; called by muse, mutect2, varscan2
- IGSF5 | c.1183C>T p.L395= | Silent (SNP) | VAF 115/304 reads (38%) | catalogued as COSV66029477; called by muse, mutect2, varscan2
- IL2RB | c.330C>T p.C110= | Silent (SNP) | VAF 84/353 reads (24%) | called by muse, mutect2, varscan2
- ITGB3 | c.1218C>T p.I406= | Silent (SNP) | VAF 148/507 reads (29%) | catalogued as rs749477357; called by muse, mutect2, varscan2
- JAG1 | c.2949G>A p.L983= | Silent (SNP) | VAF 58/287 reads (20%) | called by muse, mutect2, varscan2
- KCNQ5 | c.633C>T p.I211= | Silent (SNP) | VAF 47/150 reads (31%) | catalogued as COSV59653275; called by muse, mutect2, varscan2
- KDM1A | c.1062C>T p.A354= | Silent (SNP) | VAF 112/430 reads (26%) | called by muse, mutect2, varscan2
- KIF26B | c.4803C>T p.V1601= | Silent (SNP) | VAF 176/636 reads (28%) | called by muse, varscan2
- KRT84 | c.153T>C p.G51= | Silent (SNP) | VAF 123/485 reads (25%) | called by muse, mutect2, varscan2
- KRTAP4-8 | c.126C>T p.P42= | Silent (SNP) | VAF 185/710 reads (26%) | called by muse, mutect2
- LAMA5 | c.3513C>T p.A1171= | Silent (SNP) | VAF 84/355 reads (24%) | catalogued as rs1191624418; called by muse, mutect2, varscan2
- LTF | c.915C>T p.F305= | Silent (SNP) | VAF 79/282 reads (28%) | called by muse, mutect2, varscan2
- MAGEC1 | c.339G>A p.E113= | Silent (SNP) | VAF 173/270 reads (64%) | catalogued as rs1384966090, COSV99595764; called by muse, mutect2, varscan2
- MAGEC1 | c.1140C>T p.S380= | Silent (SNP) | VAF 183/324 reads (56%) | catalogued as rs1381874970, COSV53582428; called by muse, mutect2, varscan2
- MUC16 | c.13359C>T p.P4453= | Silent (SNP) | VAF 106/508 reads (21%) | catalogued as rs1172092398; called by muse, mutect2
- MYH7 | c.4008C>T p.A1336= | Silent (SNP) | VAF 156/444 reads (35%) | called by muse, mutect2, varscan2
- MYO16 | c.4896C>T p.F1632= | Silent (SNP) | VAF 146/578 reads (25%) | called by muse, mutect2, varscan2
- NALCN | c.1422C>T p.F474= | Silent (SNP) | VAF 47/193 reads (24%) | catalogued as rs754970097, COSV51929282; called by muse, mutect2, varscan2
- NDRG4 | c.507C>T p.L169= (on ENST00000570248 / NM_001378344.1; = p.L201= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 74/336 reads (22%) | catalogued as rs1293409689; called by muse, mutect2, varscan2
- NLRP3 | c.687G>A p.G229= | Silent (SNP) | VAF 112/400 reads (28%) | catalogued as COSV60220849; called by muse, mutect2, varscan2
- NPBWR2 | c.495C>T p.V165= | Silent (SNP) | VAF 269/724 reads (37%) | catalogued as rs149388219; called by muse, mutect2, varscan2
- NPR1 | c.1971C>T p.S657= | Silent (SNP) | VAF 99/329 reads (30%) | called by muse, mutect2, varscan2
- NYNRIN | c.1110G>A p.R370= | Silent (SNP) | VAF 129/456 reads (28%) | called by muse, mutect2, varscan2
- OR14A16 | c.138C>T p.I46= | Silent (SNP) | VAF 88/331 reads (27%) | catalogued as COSV62926556; called by muse, mutect2, varscan2
- OR1D2 | c.534C>T p.F178= | Silent (SNP) | VAF 115/347 reads (33%) | catalogued as rs1418537831, COSV104403685; called by muse, mutect2, varscan2
- OR2A2 | c.423G>A p.T141= | Silent (SNP) | VAF 286/553 reads (52%) | catalogued as rs761421065, COSV68871667; called by muse, mutect2, varscan2
- OR5B12 | c.333C>T p.F111= | Silent (SNP) | VAF 137/488 reads (28%) | catalogued as rs1246743704, COSV56904098; called by muse, mutect2, varscan2
- P2RY2 | c.630C>T p.P210= | Silent (SNP) | VAF 115/533 reads (22%) | catalogued as rs758267056; called by muse, mutect2, varscan2
- PCDHA8 | c.1731G>A p.A577= | Silent (SNP) | VAF 176/421 reads (42%) | called by muse, mutect2, varscan2
- PDE6D | c.201G>C p.S67= | Silent (SNP) | VAF 91/348 reads (26%) | called by muse, mutect2, varscan2
- PIGN | c.2628C>T p.F876= | Silent (SNP) | VAF 62/213 reads (29%) | catalogued as rs1276726166, COSV62950162; called by muse, mutect2, varscan2
- PLD5 | c.1383C>T p.F461= (on ENST00000442594; = p.F399= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/305 reads (26%) | called by muse, mutect2, varscan2
- PRG4 | c.51C>T p.F17= | Silent (SNP) | VAF 95/339 reads (28%) | catalogued as rs1232456660, COSV66623345; called by muse, mutect2, varscan2
- PRSS56 | c.1632G>A p.P544= | Silent (SNP) | VAF 180/669 reads (27%) | catalogued as rs576461097, COSV51321843; called by muse, mutect2, varscan2
- PTPRT | c.2620T>C p.L874= | Silent (SNP) | VAF 15/535 reads (3%) | called by muse, mutect2
- RBMXL3 | c.2754C>T p.G918= | Silent (SNP) | VAF 151/266 reads (57%) | called by muse, mutect2, varscan2
- RGS5 | c.171G>A p.E57= | Silent (SNP) | VAF 76/312 reads (24%) | called by muse, mutect2, varscan2
- RHBDF2 | c.649C>T p.L217= | Silent (SNP) | VAF 111/476 reads (23%) | catalogued as COSV100489686; called by muse, mutect2, varscan2
- RIPOR3 | c.444C>T p.I148= | Silent (SNP) | VAF 199/483 reads (41%) | called by muse, mutect2, varscan2
- RMND5A | c.840C>T p.S280= | Silent (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- SCRIB | c.717C>T p.L239= | Silent (SNP) | VAF 157/600 reads (26%) | catalogued as rs201346981, COSV100252454; called by muse, mutect2, varscan2
- SENP7 | c.45C>T p.I15= | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as COSV58609921; called by muse, mutect2, varscan2
- SETBP1 | c.57C>T p.F19= | Silent (SNP) | VAF 136/429 reads (32%) | called by muse, mutect2, varscan2
- SLC35C2 | c.666C>T p.L222= | Silent (SNP) | VAF 73/230 reads (32%) | called by muse, mutect2, varscan2
- SLC6A6 | c.1698C>T p.C566= | Silent (SNP) | VAF 92/288 reads (32%) | called by muse, mutect2, varscan2
- SLIT3 | c.1368C>T p.P456= | Silent (SNP) | VAF 142/357 reads (40%) | catalogued as rs369153203; called by muse, mutect2, varscan2
- SMG1 | c.228C>T p.V76= | Silent (SNP) | VAF 86/290 reads (30%) | called by muse, mutect2, varscan2
- SP8 | c.876G>A p.P292= (on ENST00000361443 / NM_198956.4; = p.P310= on NM_182700.6) | Silent (SNP) | VAF 148/723 reads (20%) | called by muse, mutect2, varscan2
- SRRM4 | c.246C>T p.T82= | Silent (SNP) | VAF 93/355 reads (26%) | catalogued as rs761868587; called by muse, mutect2, varscan2
- SRSF4 | c.1470C>T p.S490= | Silent (SNP) | VAF 148/236 reads (63%) | called by muse, mutect2, varscan2
- SSRP1 | c.1281C>T p.N427= | Silent (SNP) | VAF 98/344 reads (28%) | catalogued as rs893593134; called by muse, mutect2, varscan2
- SSU72P3 | c.387G>A p.Q129= | Silent (SNP) | VAF 108/784 reads (14%) | called by muse, mutect2, varscan2
- ST18 | c.237G>A p.E79= | Silent (SNP) | VAF 99/412 reads (24%) | catalogued as COSV52508961; called by muse, mutect2, varscan2
- ST8SIA3 | c.573C>T p.F191= | Silent (SNP) | VAF 101/365 reads (28%) | catalogued as rs376754702; called by muse, mutect2, varscan2
- TDRD5 | c.1470C>T p.I490= | Silent (SNP) | VAF 79/298 reads (27%) | catalogued as COSV54239102; called by muse, mutect2, varscan2
- TDRD9 | c.1614G>A p.V538= | Silent (SNP) | VAF 90/329 reads (27%) | called by muse, mutect2, varscan2
- TRIM25 | c.1356C>T p.L452= | Silent (SNP) | VAF 80/285 reads (28%) | called by muse, mutect2, varscan2
- TRPM3 | c.822C>T p.Y274= (on ENST00000357533 / NM_001366142.2; = p.Y119= on NM_020952.6) | Silent (SNP) | VAF 161/285 reads (56%) | catalogued as rs765605289; called by muse, mutect2, varscan2
- TTLL2 | c.1473G>A p.E491= | Silent (SNP) | VAF 80/353 reads (23%) | catalogued as rs1208372017, COSV53444936; called by muse, mutect2, varscan2
- TTN | c.39588A>G p.A13196= (on ENST00000591111; = p.A5772= on NM_003319.4) | Silent (SNP) | VAF 79/304 reads (26%) | catalogued as rs1205699868; called by muse, mutect2, varscan2
- TTN | c.24132C>T p.F8044= (on ENST00000591111; = p.F7117= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as COSV60105479; called by muse, mutect2, varscan2
- UBASH3A | c.1377C>T p.F459= | Silent (SNP) | VAF 71/269 reads (26%) | called by muse, mutect2, varscan2
- ZC3H11B | c.1068C>T p.I356= | Silent (SNP) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- ZNF106 | c.5079C>T p.L1693= | Silent (SNP) | VAF 82/279 reads (29%) | called by muse, mutect2, varscan2
- ZNF106 | c.3468C>T p.F1156= | Silent (SNP) | VAF 105/345 reads (30%) | catalogued as rs1006978859; called by mutect2, varscan2
- ZNF541 | c.3951G>A p.V1317= | Silent (SNP) | VAF 121/432 reads (28%) | called by muse, mutect2, varscan2
- ZNF781 | c.708G>A p.R236= | Silent (SNP) | VAF 82/327 reads (25%) | called by muse, mutect2, varscan2
- AC092070.2 | n.1240C>T | RNA (SNP) | VAF 67/284 reads (24%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5990476 G>A | 5'Flank (SNP) | VAF 79/302 reads (26%) | catalogued as rs557839912; called by muse, mutect2, varscan2
- C4orf50 | chr4:5990477 G>A | 5'Flank (SNP) | VAF 81/305 reads (27%) | called by muse, mutect2, varscan2
- CAMK2A | c.*1275C>T | 3'UTR (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- CDH2 | c.173-22568C>T | Intron (SNP) | VAF 56/187 reads (30%) | catalogued as rs1006337226, COSV52291480; called by muse, mutect2, varscan2
- CLN8 | c.543+1367C>T | Intron (SNP) | VAF 76/342 reads (22%) | called by muse, mutect2
- CPLANE1 | c.*3241G>A | 3'UTR (SNP) | VAF 92/215 reads (43%) | called by muse, mutect2, varscan2
- ELP4 | c.1147-63920G>A | Intron (SNP) | VAF 41/267 reads (15%) | called by muse, mutect2
- ICA1 | c.804+87_804+89del | Intron (DEL) | VAF 76/374 reads (20%) | called by pindel, varscan2
- IGFN1 | c.1242-517C>T | Intron (SNP) | VAF 146/449 reads (33%) | catalogued as rs767436817; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+24386G>A | Intron (SNP) | VAF 76/262 reads (29%) | called by muse, mutect2, varscan2
- MLIP | c.613-11424G>A | Intron (SNP) | VAF 153/460 reads (33%) | catalogued as COSV99229535; called by muse, mutect2, varscan2
- MRAP | chr21:32314600 C>T | 3'Flank (SNP) | VAF 122/376 reads (32%) | catalogued as COSV57936657; called by muse, mutect2, varscan2
- OR2T2 | chr1:248441543 C>T | 5'Flank (SNP) | VAF 18/84 reads (21%) | catalogued as rs772269536; called by mutect2, varscan2
- SH2D3C | c.516-5385C>T | Intron (SNP) | VAF 292/506 reads (58%) | called by muse, mutect2, varscan2
- TMEM30A-DT | n.296+10616T>C | Intron (SNP) | VAF 86/291 reads (30%) | called by muse, mutect2, varscan2
- WSCD1 | chr17:6069299 G>A | 5'Flank (SNP) | VAF 73/261 reads (28%) | called by muse, mutect2, varscan2
